Somatic mutation profile of tumor specimen TCGA-KN-8418-01A (aliquot TCGA-KN-8418-01A-11D-2310-10) from TCGA case TCGA-KN-8418, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 41.3 years (15,086 days).
Specimen TCGA-KN-8418-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 557d0e8f-952c-4388-bdf1-286765e2e500.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KN-8418-11A (Solid Tissue Normal), aliquot TCGA-KN-8418-11A-01D-2310-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4466633e-e40b-4afd-bca1-22daf3c85906

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 5, Splice Region 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.534C>A p.H178Q | Missense Mutation (SNP) | VAF 49/60 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555526001, CM1313554, COSV52741277, COSV53120340, COSV53165113, COSV53624003; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- BDNF | c.665G>A p.S222N | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100151687; called by muse, mutect2
- FAM86B2 | c.243C>A p.H81Q | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as COSV99266871; called by muse, mutect2, varscan2
- NOTCH1 | c.5716G>A p.A1906T | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.592); catalogued as rs779880917; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TIAM1 | c.1162C>T p.R388W | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1222262650, COSV99737107; called by muse, mutect2
- BACE1 | c.730_732del p.L244del | In Frame Del (DEL) | VAF 37/84 reads (44%) | called by mutect2, pindel, varscan2
- CEP19 | c.409G>T p.V137F | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- ELFN1 | c.1148C>T p.S383F | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXO41 | c.977A>C p.Q326P | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, varscan2
- SEPTIN2 | c.840C>A p.L280= | Splice Region (SNP) | VAF 34/40 reads (85%) | called by muse, mutect2, varscan2
- BPTF | c.2478C>T p.T826= | Silent (SNP) | VAF 8/210 reads (4%) | catalogued as rs1226617683; called by muse, mutect2
- CACNA1A | c.5535C>T p.D1845= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as rs372083869, COSV64213567; called by muse, mutect2, varscan2
- MROH2B | c.1833G>A p.E611= | Silent (SNP) | VAF 43/97 reads (44%) | catalogued as COSV68186675; called by muse, mutect2, varscan2
- NAGA | c.1140C>T p.L380= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV67170317; called by muse, mutect2, varscan2
- SPINT2 | c.627G>A p.L209= | Silent (SNP) | VAF 45/113 reads (40%) | catalogued as COSV100007717; called by muse, mutect2, varscan2
- IER2 | c.*634A>T | 3'UTR (SNP) | VAF 27/51 reads (53%) | catalogued as COSV99460281; called by muse, mutect2, varscan2
